CCDI case PBCLRC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/fc8bdc92-9660-4183-9ec4-5d897685e009

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Granulosa cell tumor, malignant: ICD-O-3 morphology code: 8620/3; Tissue or organ of origin: Ovary; Age at diagnosis: 12.2 years (4,447 days).

Biospecimens (3 samples)
- Sample 0DV5RP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DV5S2, 0DV5SI (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
